EXCEPTIONAL_RESPONDERS case ER-B0AB — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/60ec62c8-d041-46c1-b632-591b2d0cc5b9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (2)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.6 years (18,862 days); AJCC clinical stage: Stage III.
2. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: recurrence; Age at diagnosis: 55.3 years (20,207 days); Year of diagnosis: 2008; AJCC clinical stage: Stage I; Prior malignancy: yes; Days to last follow up: 2,921 days (8.0 years); Days to best overall response: 959 days (2.6 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 852 days (2.3 years); Days to treatment end: 880 days (2.4 years).

Follow-up (1 entry)
- Days to follow up: 2,921 days (8.0 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 321 days; Days progression-free: 2,921 days (8.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0AB-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0AB-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
